CCDI case PBBZKE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ad350eac-da44-4c39-ab40-9f5eb1899692

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 6.3 years (2,301 days).

Biospecimens (3 samples)
- Sample 0DLRHJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLRHT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DLRI4: Tissue type: Tumor; Specimen type: Solid Tissue.
